Gene-level copy-number profile of tumor specimen TCGA-HS-A5N9-01A from TCGA case TCGA-HS-A5N9, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Uterus, NOS; Age at diagnosis: 58.8 years (21,463 days).
Specimen TCGA-HS-A5N9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.58815c5e-d54a-4e3d-83b5-6e2ae5bf6c56.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HS-A5N9-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2.
https://portal.gdc.cancer.gov/files/6c84acc1-dacc-465d-b7b8-b8b9449726f8

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,777; copy number 2: 5,975; copy number 3: 27,357; copy number 4: 18,122; copy number 5: 1,893; copy number 6: 3,151; copy number 7: 398; copy number 8: 136.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 534 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:70,972–4,269,000, 87 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr8:107,499,773–142,403,182, 402 genes, copy number 7–8 (within-gene range 4–8) (broad region; genes not listed).
- chr12:30,086,342–30,492,302, 8 genes, copy number 8: AC023511.3, AC023511.2, AC023511.1, LINC02386, AC078776.2, RNA5SP356, AC078776.1, AC026371.1.
- chr20:20,659,710–22,343,930, 37 genes, copy number 7: EIF4E2P1, LLPHP1, RN7SL607P, MRPS11P1, AL133465.1, LINC00237, AL121759.2, RPL24P2, KIZ, RNA5SP477, AL121759.1, KIZ-AS1, RPS15AP1, ZNF877P, AL117332.1, XRN2, NKX2-4, AL158013.1, RN7SKP140, AL133325.1, AL133325.3, GSTM3P1, NKX2-2, NKX2-2-AS1, AL133325.2, LINC01727, LINC01726, AL121590.1, PAX1, SLC25A6P1, RPL41P1, AL109807.1, LINC01432, AL035258.1, LINC01427, AL049737.1, AL121912.1.

Autosomal genes at a single copy (total copy number 1): 2,242. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
